Somatic mutation profile of tumor specimen TCGA-29-1777-01A (aliquot TCGA-29-1777-01A-01W-0639-09) from TCGA case TCGA-29-1777, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 47.5 years (17,356 days).
Specimen TCGA-29-1777-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f836463-fec0-48a4-bfa6-119a14073fb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1777-10A (Blood Derived Normal), aliquot TCGA-29-1777-10A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87af14d6-dedd-4054-a05e-fdbce38fd7ee

The open-access MAF lists 144 somatic variants for this specimen: 112 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 29, Nonsense Mutation 6, Frame Shift Del 5, In Frame Del 4, Splice Site 4, Frame Shift Ins 2, Intron 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.1360+2T>A p.X454_splice | Splice Site (SNP) | VAF 10/38 reads (26%) | catalogued as COSV65388661; called by muse, mutect2, varscan2
- ADGRG6 | c.2209G>T p.D737Y | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV51588701; called by muse, mutect2, varscan2
- AL136295.1 | c.2281T>G p.F761V | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV55778755; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.7022A>T p.N2341I | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as COSV51851448; called by muse, mutect2
- AQP6 | c.247C>A p.P83T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59646070; called by muse, mutect2, varscan2
- ARL5B | c.232A>G p.N78D | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV66011028; called by muse, mutect2, varscan2
- AVPI1 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs146044000, COSV65697367; called by muse, mutect2, varscan2
- C10orf71 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60505818; called by muse, mutect2, varscan2
- CARM1 | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53403081; called by muse, mutect2, varscan2
- CASP8 | c.870G>C p.E290D (on ENST00000432109 / NM_033355.3; = p.E307D on NM_001228.4) | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99630749; called by muse, mutect2
- CCT4 | c.1585A>G p.I529V | Missense Mutation (SNP) | VAF 88/359 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV66701199; called by muse, mutect2, varscan2
- CCT8L2 | c.131C>A p.A44D | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63461934; called by muse, mutect2, varscan2
- CDC23 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.696); catalogued as COSV67509559; called by muse, mutect2, varscan2
- CFAP94 | c.1333G>T p.V445L (on ENST00000320267 / NM_001352064.2; = p.V451L on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/267 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV57230816; called by muse, mutect2, varscan2
- CYP11B1 | c.41C>G p.P14R | Missense Mutation (SNP) | VAF 55/304 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV52825743; called by muse, mutect2, varscan2
- DDHD2 | c.1301G>T p.R434I | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68157456; called by muse, mutect2, varscan2
- DHX33 | c.1289C>A p.T430N | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as COSV56578187; called by muse, mutect2, varscan2
- DOCK10 | c.5823C>A p.D1941E | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs1257617800, COSV51361256; called by muse, mutect2, varscan2
- DRC1 | c.1387A>T p.M463L | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV56529976; called by muse, mutect2, varscan2
- EDEM2 | c.1385G>T p.G462V | Missense Mutation (SNP) | VAF 82/219 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV100788029; called by muse, mutect2, varscan2
- EDEM2 | c.1384G>C p.G462R | Missense Mutation (SNP) | VAF 81/216 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV100788030; called by muse, mutect2, varscan2
- EMSY | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 28/399 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.294); catalogued as COSV100595983; called by muse, mutect2
- F5 | c.1119-1G>C p.X373_splice | Splice Site (SNP) | VAF 98/265 reads (37%) | catalogued as COSV100889171, COSV63122134; called by muse, mutect2, varscan2
- GCC1 | c.1372A>T p.K458* | Nonsense Mutation (SNP) | VAF 8/136 reads (6%) | catalogued as COSV100365632; called by muse, mutect2
- GCC1 | c.1371G>T p.E457D | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as COSV100365634; called by muse, mutect2
- GLUL | c.998A>G p.K333R | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV59381869; called by muse, mutect2, varscan2
- GPR155 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 20/600 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99790177; called by muse, mutect2
- HHAT | c.1465A>T p.T489S | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.22); catalogued as COSV54793616; called by muse, mutect2, varscan2
- HMCN1 | c.9180C>A p.D3060E | Missense Mutation (SNP) | VAF 17/277 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as rs1391191047, COSV99634333; called by muse, mutect2
- HUWE1 | c.9691C>A p.Q3231K | Missense Mutation (SNP) | VAF 180/241 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV53338879; called by muse, mutect2, varscan2
- IL17RA | c.598+1G>A p.X200_splice | Splice Site (SNP) | VAF 41/124 reads (33%) | catalogued as rs759315432, COSV60052000; called by muse, mutect2, varscan2
- IL36B | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 99/293 reads (34%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.009); catalogued as COSV52084955, COSV52089856; called by muse, mutect2, varscan2
- IQCC | c.977G>C p.R326T | Missense Mutation (SNP) | VAF 111/225 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV52208068; called by muse, varscan2
- ITGA2B | c.2468G>C p.G823A | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); catalogued as CM153666, COSV52231778, COSV99288414; called by muse, mutect2, varscan2
- ITGBL1 | c.803C>T p.T268I | Missense Mutation (SNP) | VAF 200/492 reads (41%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.998); catalogued as COSV66006571, COSV66010651; called by muse, mutect2, varscan2
- KIF1A | c.170G>T p.W57L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV57485388; called by muse, mutect2, varscan2
- KIF26B | c.584A>T p.K195M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV68572282; called by muse, mutect2, varscan2
- KIF3C | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV53098327; called by muse, mutect2, varscan2
- KPNA2 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 48/545 reads (9%) | catalogued as COSV57857407; called by muse, mutect2
- KRTAP3-3 | c.80G>C p.R27P | Missense Mutation (SNP) | VAF 69/119 reads (58%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.998); catalogued as COSV101195963, COSV101195983; called by muse, mutect2, varscan2
- LEF1 | c.280+1G>T p.X94_splice | Splice Site (SNP) | VAF 60/75 reads (80%) | catalogued as COSV54465363; called by muse, mutect2, varscan2
- LGALS2 | c.205C>G p.Q69E | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.192); catalogued as COSV50755887; called by muse, mutect2, varscan2
- MAGI3 | c.3727C>G p.L1243V | Missense Mutation (SNP) | VAF 26/428 reads (6%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV100290135; called by muse, mutect2
- MCM3AP | c.4398T>G p.S1466R | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as rs773755111, COSV52437854; called by muse, mutect2, varscan2
- MDGA2 | c.2213T>G p.V738G (on ENST00000399232 / NM_001113498.2; = p.V440G on NM_182830.4) | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV62083301, COSV62119459; called by muse, mutect2, varscan2
- MYH2 | c.3232G>T p.E1078* | Nonsense Mutation (SNP) | VAF 75/118 reads (64%) | catalogued as COSV55433950; called by muse, mutect2, varscan2
- MYH4 | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99702021; called by muse, mutect2
- MYH7 | c.4520A>G p.E1507G | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.405); catalogued as COSV62517519; called by muse, mutect2, varscan2
- MYH7 | c.3082G>C p.E1028Q | Missense Mutation (SNP) | VAF 100/311 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV62517528; called by muse, mutect2, varscan2
- NBAS | c.4412G>A p.G1471E | Missense Mutation (SNP) | VAF 486/1165 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55716146, COSV99869031; called by muse, mutect2, varscan2
- NELL2 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs372382047; called by muse, mutect2, varscan2
- NLRP13 | c.1212A>T p.E404D | Missense Mutation (SNP) | VAF 113/253 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.037); catalogued as COSV61620193, COSV61623429; called by muse, mutect2, varscan2
- NSD1 | c.290T>A p.F97Y | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.259); catalogued as rs200193622, COSV61772960; called by muse, mutect2, varscan2
- NYAP2 | c.890C>A p.A297D | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV99798112; called by muse, mutect2
- OBSCN | c.11538C>G p.Y3846* | Nonsense Mutation (SNP) | VAF 98/259 reads (38%) | catalogued as rs755214451, COSV52754819; called by muse, mutect2, varscan2
- OLFM1 | c.336C>G p.D112E (on ENST00000371793 / NM_001282611.2; = p.D94E on NM_006334.4) | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.63); catalogued as COSV52961855; called by muse, mutect2, varscan2
- P4HB | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV58942197; called by muse, mutect2
- PARP10 | c.934C>G p.P312A | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs1449873775, COSV57297166; called by muse, mutect2, varscan2
- PCDHGA2 | c.381C>A p.N127K | Missense Mutation (SNP) | VAF 112/317 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs750765335, COSV53917444, COSV99544762; called by muse, mutect2, varscan2
- PCDHGB1 | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV53959753; called by muse, mutect2
- PDE1C | c.628G>T p.V210F | Missense Mutation (SNP) | VAF 88/352 reads (25%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.856); catalogued as COSV58507201; called by muse, mutect2, varscan2
- PHF20L1 | c.2221G>A p.D741N | Missense Mutation (SNP) | VAF 15/492 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55188416; called by muse, mutect2
- PIK3C2G | c.1547A>T p.Y516F | Missense Mutation (SNP) | VAF 81/315 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs746002413, COSV56802488; called by muse, mutect2, varscan2
- PPM1F | c.1183G>C p.A395P | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54283454; called by muse, mutect2, varscan2
- RNF41 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 12/432 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100560323; called by muse, mutect2
- ROBO1 | c.233T>G p.I78S | Missense Mutation (SNP) | VAF 129/278 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71392668; called by muse, mutect2, varscan2
- ROCK2 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 95/259 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV55077093; called by muse, mutect2, varscan2
- SERPINE2 | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.307); catalogued as rs1559193488, COSV51456476; called by muse, varscan2
- SLC25A39 | c.238G>A p.G80S (on ENST00000377095 / NM_001143780.3; = p.G72S on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56586774; called by muse, mutect2, varscan2
- SLC7A13 | c.515G>C p.S172T | Missense Mutation (SNP) | VAF 186/467 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.369); catalogued as rs891536339, COSV52533257; called by muse, mutect2, varscan2
- SLC9A5 | c.1775G>T p.G592V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.212); catalogued as COSV100237678, COSV55360980; called by muse, mutect2, varscan2
- SMC1B | c.247A>T p.I83L | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV61581255; called by muse, varscan2
- SOX5 | c.1297G>T p.V433F | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.09); catalogued as COSV58622990; called by muse, mutect2, varscan2
- SPNS3 | c.1081G>T p.V361F | Missense Mutation (SNP) | VAF 71/101 reads (70%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as rs772101349, COSV61069448; called by muse, mutect2, varscan2
- SRSF11 | c.1088G>C p.R363T | Missense Mutation (SNP) | VAF 77/285 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV63936768; called by muse, mutect2, varscan2
- SULT1A1 | c.11T>C p.I4T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as COSV59087218; called by muse, mutect2, varscan2
- SUPT6H | c.2077T>A p.Y693N | Missense Mutation (SNP) | VAF 95/119 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58925700; called by muse, mutect2, varscan2
- SWAP70 | c.281G>T p.C94F | Missense Mutation (SNP) | VAF 63/94 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59662980; called by muse, varscan2
- SZT2 | c.4597G>T p.D1533Y (on ENST00000634258 / NM_001365999.1; = p.D1476Y on NM_015284.4) | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV65168299; called by muse, mutect2, varscan2
- TBC1D4 | c.2440G>C p.E814Q | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as COSV66488272; called by muse, mutect2, varscan2
- TBC1D8B | c.2759C>A p.S920* | Nonsense Mutation (SNP) | VAF 14/113 reads (12%) | catalogued as COSV52177067; called by mutect2, varscan2
- TCN2 | c.125T>C p.M42T | Missense Mutation (SNP) | VAF 95/252 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); catalogued as COSV53190931; called by muse, mutect2, varscan2
- TEX14 | c.4202G>T p.R1401I (on ENST00000240361 / NM_001201457.2; = p.R1355I on NM_031272.5) | Missense Mutation (SNP) | VAF 108/161 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53613784; called by muse, mutect2, varscan2
- TG | c.3455T>C p.L1152P | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.096); catalogued as COSV55069966; called by muse, mutect2, varscan2
- THAP9 | c.1572G>T p.R524S | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV56355941; called by muse, varscan2
- TMEM200A | c.567G>C p.M189I | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV51660646, COSV99759845; called by muse, mutect2
- TMEM74 | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.124); catalogued as COSV52462806; called by muse, mutect2, varscan2
- TP63 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 168/308 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV53199759; called by muse, mutect2, varscan2
- TRAPPC8 | c.1421C>A p.P474Q | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.663); catalogued as COSV51968636; called by muse, mutect2, varscan2
- TRIM56 | c.1700G>C p.S567T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV60157799; called by muse, mutect2, varscan2
- TRIO | c.2116G>T p.V706L | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.964); catalogued as COSV60079884, COSV60100141; called by muse, mutect2, varscan2
- TTC30A | c.1868G>T p.G623V | Missense Mutation (SNP) | VAF 159/551 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV63100927; called by muse, mutect2, varscan2
- TTN | c.9893T>C p.L3298P (on ENST00000591111; = p.L3252P on NM_003319.4) | Missense Mutation (SNP) | VAF 79/186 reads (42%) | PolyPhen probably damaging (0.999); catalogued as COSV59949221; called by muse, mutect2, varscan2
- UGT2A3 | c.589A>T p.T197S | Missense Mutation (SNP) | VAF 64/102 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV52359397; called by muse, mutect2, varscan2
- VIPAS39 | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 108/267 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs747233166, COSV58938979; called by muse, mutect2, varscan2
- VWF | c.4273A>T p.I1425F | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs61750083, CM971581, COSV99779919; ClinVar: not provided; called by muse, mutect2, varscan2
- WWP2 | c.1802del p.H601Pfs*8 | Frame Shift Del (DEL) | VAF 26/77 reads (34%) | catalogued as COSV63123965; called by mutect2, pindel, varscan2
- ZFPM2 | c.2310T>A p.C770* | Nonsense Mutation (SNP) | VAF 42/110 reads (38%) | catalogued as COSV65872936; called by muse, mutect2, varscan2
- ZMYND8 | c.1450G>A p.A484T (on ENST00000311275 / NM_001363741.2; = p.A504T on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/79 reads (65%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.92); catalogued as COSV53684601; called by muse, mutect2, varscan2
- ZNF226 | c.590G>T p.C197F | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV56196234; called by muse, mutect2, varscan2
- ZNF333 | c.215C>G p.T72R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.1); catalogued as COSV52885269; called by muse, mutect2, varscan2
- ZNF560 | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 96/225 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.018); catalogued as rs61743338, COSV56872657; called by muse, mutect2, varscan2
- ADAMTS1 | c.1753del p.E585Nfs*94 | Frame Shift Del (DEL) | VAF 23/167 reads (14%) | called by mutect2, pindel, varscan2
- AL136295.1 | c.2299_2317delinsA p.S767_V773delinsI | In Frame Del (DEL) | VAF 37/121 reads (31%) | called by pindel, varscan2*
- CDK11A | c.207_227del p.E70_R76del | In Frame Del (DEL) | VAF 12/24 reads (50%) | called by mutect2, pindel
- CHSY1 | c.1313_1323del p.R438Hfs*5 | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | called by mutect2, pindel, varscan2
- NOTCH3 | c.2084dup p.S696Efs*7 | Frame Shift Ins (INS) | VAF 5/22 reads (23%) | called by mutect2, pindel
- NRIP1 | c.3155_3180del p.N1052Ifs*37 | Frame Shift Del (DEL) | VAF 109/408 reads (27%) | called by mutect2, pindel, varscan2
- PDE6C | c.40_45del p.E14_E15del | In Frame Del (DEL) | VAF 35/60 reads (58%) | called by mutect2, pindel, varscan2
- RFPL3 | c.397_426del p.T133_D142del (on ENST00000249007 / NM_001098535.1; = p.T104_D113del on NM_006604.2) | In Frame Del (DEL) | VAF 24/144 reads (17%) | called by mutect2, pindel, varscan2
- SPTB | c.2046del p.F682Lfs*37 | Frame Shift Del (DEL) | VAF 32/93 reads (34%) | called by mutect2, pindel, varscan2
- WDPCP | c.491_493delinsCCAT p.I164Tfs*3 | Frame Shift Ins (INS) | VAF 126/518 reads (24%) | called by pindel, varscan2*
- ACSM1 | c.954A>G p.S318= | Silent (SNP) | VAF 96/236 reads (41%) | catalogued as COSV54634068; called by mutect2, varscan2
- ALK | c.3426A>C p.P1142= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV66561956; called by muse, mutect2, varscan2
- ANKRD11 | c.177G>A p.K59= | Silent (SNP) | VAF 15/19 reads (79%) | catalogued as COSV56357707; called by muse, mutect2, varscan2
- ANKRD34B | c.336C>T p.S112= | Silent (SNP) | VAF 9/191 reads (5%) | catalogued as COSV100103622; called by muse, mutect2
- APC | c.2574T>C p.I858= | Silent (SNP) | VAF 217/270 reads (80%) | catalogued as COSV57333071; called by muse, mutect2, varscan2
- CNNM3 | c.2082C>G p.G694= | Silent (SNP) | VAF 42/109 reads (39%) | catalogued as COSV59708911, COSV59709730; called by muse, mutect2, varscan2
- CRISPLD1 | c.39A>C p.T13= | Silent (SNP) | VAF 176/466 reads (38%) | catalogued as COSV51545777; called by muse, mutect2, varscan2
- DCTN1 | c.1698C>A p.A566= | Silent (SNP) | VAF 30/460 reads (7%) | catalogued as COSV100721043, COSV100721129; called by muse, mutect2
- DNA2 | c.147G>C p.V49= | Silent (SNP) | VAF 72/112 reads (64%) | catalogued as COSV64427968; called by muse, mutect2, varscan2
- GP2 | c.1471C>T p.L491= (on ENST00000381362 / NM_001007240.3; = p.L488= on NM_001502.4) | Silent (SNP) | VAF 167/429 reads (39%) | catalogued as COSV56892634; called by muse, mutect2, varscan2
- IGKV2D-24 | c.135T>C p.S45= | Silent (SNP) | VAF 189/672 reads (28%) | catalogued as rs762869599; called by muse, mutect2, varscan2
- KHDRBS2 | c.495T>C p.D165= | Silent (SNP) | VAF 67/204 reads (33%) | catalogued as COSV55436991; called by muse, mutect2, varscan2
- KIF14 | c.3207G>A p.Q1069= | Silent (SNP) | VAF 133/351 reads (38%) | catalogued as COSV100951023; called by muse, mutect2, varscan2
- KRTAP6-1 | c.36C>A p.T12= | Silent (SNP) | VAF 56/275 reads (20%) | catalogued as COSV58167981, COSV58168644; called by muse, mutect2, varscan2
- LAG3 | c.750C>T p.N250= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs1295298437, COSV52566786; called by muse, mutect2, varscan2
- MYO1E | c.1983G>C p.S661= | Silent (SNP) | VAF 31/48 reads (65%) | catalogued as rs753049686, COSV55684026; called by muse, mutect2, varscan2
- NLRP13 | c.1374T>C p.Y458= | Silent (SNP) | VAF 91/237 reads (38%) | catalogued as rs930750556, COSV61619640, COSV61620717; called by muse, mutect2, varscan2
- PLEKHM1 | c.291C>A p.T97= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as rs531876914, COSV101378852; called by muse, mutect2
- PLXDC2 | c.291G>A p.L97= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as COSV65913506; called by muse, mutect2, varscan2
- POSTN | c.132T>C p.C44= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as COSV65712339; called by muse, mutect2, varscan2
- RASA3 | c.1332T>C p.S444= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV61865324; called by muse, mutect2, varscan2
- SI | c.2259G>A p.V753= | Silent (SNP) | VAF 14/257 reads (5%) | catalogued as COSV52290846; called by muse, mutect2
- SUGP2 | c.1236G>T p.V412= | Silent (SNP) | VAF 92/181 reads (51%) | catalogued as COSV58256533; called by muse, mutect2, varscan2
- TAS2R60 | c.918G>T p.V306= | Silent (SNP) | VAF 18/668 reads (3%) | called by muse, mutect2
- TNS1 | c.3843C>T p.G1281= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV50694158; called by muse, mutect2, varscan2
- TPRG1L | c.709C>T p.L237= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV54560557; called by muse, mutect2, varscan2
- TTC7A | c.2094C>A p.V698= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV55409664; called by muse, mutect2, varscan2
- VCAN | c.2187T>C p.S729= | Silent (SNP) | VAF 83/128 reads (65%) | catalogued as COSV54100187; called by muse, mutect2, varscan2
- ZCCHC7 | c.867T>G p.P289= | Silent (SNP) | VAF 20/384 reads (5%) | catalogued as COSV100383431; called by muse, mutect2
- DST | c.1146-276A>G | Intron (SNP) | VAF 83/210 reads (40%) | catalogued as COSV55004143; called by muse, mutect2, varscan2
- SECISBP2 | chr9:89362400 G>C | 3'Flank (SNP) | VAF 10/78 reads (13%) | catalogued as COSV100358702; called by muse, varscan2
- TTN | c.10360+1914A>G | Intron (SNP) | VAF 100/258 reads (39%) | catalogued as COSV59949214; called by muse, mutect2
